Gene-level copy-number profile of tumor specimen TCGA-N7-A4Y8-01A from TCGA case TCGA-N7-A4Y8, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IVB; Age at diagnosis: 73.0 years (26,650 days).
Specimen TCGA-N7-A4Y8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.c28c7168-a9e6-498f-96a7-1a97c85b5fe1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N7-A4Y8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/139ab695-c497-4c55-8bba-f034976cd00d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 1,240; copy number 2: 25,394; copy number 3: 13,190; copy number 4: 19,057; copy number 5: 832; copy number 6: 83; copy number 8: 7; copy number 9: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N7-A4Y8-01A-11D-A28Q-01): tumor purity 0.91, ploidy 2.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,709,235–116,932,238, 5 genes (within-gene range 0–1): TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901.
- chr4:181,260,442–181,265,145, 1 gene: LINC02500.
- chr16:79,264,454–79,264,573, 1 gene: RNA5SP431.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 926 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,100,305–9,614,877, 13 genes, copy number 5: GPR157, MIR34AHG, MIR34A, LNCTAM34A, H6PD, SPSB1, BX323043.1, LINC02606, RNA5SP40, AL928921.1, SLC25A33, AL954705.1, TMEM201.
- chr1:13,474,973–16,231,335, 70 genes, copy number 5–9 (broad region; genes not listed).
- chr1:164,828,436–165,661,796, 14 genes, copy number 5: AL357568.1, Y_RNA, RPL35AP7, RNU6-755P, LMX1A, LMX1A-AS2, LMX1A-AS1, RXRG, LRRC52-AS1, PRELID1P7, LRRC52, AL356441.2, AL356441.1, MGST3.
- chr1:165,662,585–165,671,725, 2 genes, copy number 5: Y_RNA, AL451074.3.
- chr1:203,626,787–203,744,081, 1 gene, copy number 5 (within-gene range 4–5): ATP2B4.
- chr1:203,729,581–205,022,822, 42 genes, copy number 5 (within-gene range 4–5): SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1.
- chr1:234,644,666–234,980,804, 13 genes, copy number 5: AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3.
- chr2:65,203,502–65,227,605, 1 gene, copy number 6 (within-gene range 4–6): AC007318.1.
- chr2:65,227,788–66,200,373, 13 genes, copy number 6 (within-gene range 4–6): ACTR2, SPRED2, AC012370.1, AC007389.1, AC012370.2, DNAJB12P1, RPS15AP15, RN7SL635P, VTRNA2-2P, AC007389.2, AC007389.3, KRT18P33, AC007741.1.
- chr2:68,023,694–68,261,230, 7 genes, copy number 6 (within-gene range 4–6): FBXL12P1, C1D, AC017083.4, WDR92, PPIAP64, AC017083.3, PNO1.
- chr2:68,179,833–68,180,532, 1 gene, copy number 6: AC017083.2.
- chr2:85,602,856–86,338,083, 23 genes, copy number 6 (within-gene range 4–6): USP39, C2orf68, SFTPB, GNLY, GPR160P1, RNU1-38P, ATOH8, MIR6071, AC105053.1, RN7SKP83, ST3GAL5, ST3GAL5-AS1, AC012511.1, AC012511.2, POLR1A, PTCD3, SNORD94, IMMT, Y_RNA, MIR4779, AC009309.1, MRPL35, REEP1.
- chr2:113,067,970–140,221,485, 447 genes, copy number 5–6 (broad region; genes not listed).
- chr2:140,234,737–140,899,106, 4 genes, copy number 5: AC092156.1, MIR7157, COPRSP1, LRRC57P1.
- chr2:158,127,957–158,682,879, 7 genes, copy number 8 (within-gene range 4–8): UPP2-IT1, CCDC148-AS1, CCDC148, HNRNPDLP2, RN7SL393P, PKP4, RPL7AP22.
- chr6:150,061,053–150,250,392, 3 genes, copy number 5 (within-gene range 3–5): ULBP3, PPP1R14C, AL355497.3.
- chr7:149,126,416–149,255,606, 4 genes, copy number 5: ZNF398, AC004890.1, ZNF282, ZNF212.
- chr8:117,794,490–118,111,826, 1 gene, copy number 5 (within-gene range 4–5): EXT1.
- chr11:65,444,458–65,797,219, 34 genes, copy number 5: MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1, LTBP3, AP001362.1, ZNRD2-AS1, ZNRD2, FAM89B, EHBP1L1, KCNK7, MAP3K11, PCNX3, MIR4690, SIPA1, MIR4489, RELA, RELA-DT, RN7SL309P, KAT5, RNASEH2C, KRT8P26, AP001266.2, AP5B1, OVOL1, OVOL1-AS1, AP001266.1.
- chr12:50,112,082–50,887,884, 23 genes, copy number 5 (within-gene range 4–5): COX14, AC074032.1, CERS5, LIMA1, AC008147.2, AC008147.3, AC008147.1, MIR1293, RNU6-1093P, AC008147.4, FAM186A, AC090058.1, LARP4, DIP2B, RNU6-769P, RNU6-238P, Y_RNA, AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3.
- chr17:49,966,075–50,016,844, 4 genes, copy number 5 (within-gene range 4–5): RNU6-1313P, DLX4, DLX3, AC009720.1.
- chr18:58,481,247–58,629,091, 1 gene, copy number 5 (within-gene range 3–5): ALPK2.
- chr18:58,557,070–59,386,749, 23 genes, copy number 5: AC104971.2, SNORA108, RPL9P31, AC104971.3, AC104971.1, MALT1, AC104365.1, MRPL37P1, AC104365.3, AC104365.2, RNU6-219P, LINC01926, U8, ZNF532, RNU2-69P, OACYLP, AC040963.1, SEC11C, GRP, RAX, CPLX4, LMAN1, AC016229.2.
- chr18:59,459,072–59,465,682, 1 gene, copy number 5: AC016229.1.
- chr19:27,638,483–31,147,981, 70 genes, copy number 5 (broad region; genes not listed).
- chr20:35,115,364–38,337,505, 104 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,237. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
